Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A44S, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A44S-01A (Primary Tumor).

Procurement Date. Laterality: Squamous cell carcinoma of the cervix, non-keratinizing, G-2, with invasion of the whole endocervix and focal invasion into the upper third of vagina. Tumor size is 6x3x4 cm, tumor is 3 cm thick. Endometrium is of proliferative type. In the right ovary there are serous cystadenoma, follicular cyst, luteal body with hemorrhages. Left ovary is with follicular cyst, fibrous bodies. Fallopian tubes are of normal structure. Five lymph nodes on the right were examined, four lymph nodes demonstrated tumor metastases. Five examined lymph nodes on the left demonstrated reactive changes.

Path Report: CERVIX TISSUE CHECKLIST

Specimen type: Simple hysterectomy

Tumor site: Endocervix

Tumor size: 3 x 4 x 6 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Lesion greater than 4.0 cm

Lymph nodes: 4/10 positive for metastasis (Pelvic lymph nodes 4/10)

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3
Carcinoma, squamous cell, NOS
8070/3
Site: cervix, NOS
C53.9 8/31/12
RD

fw
8/14/12

Source: NCI Genomic Data Commons file f40424de-b70a-4649-b2ac-69b75e978cad (TCGA-EA-A44S.25D56763-173A-4F45-AA4E-118382CD2296.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).